Somatic mutation profile of tumor specimen C3N-02422-01 (aliquot CPT0146880010) from CPTAC case C3N-02422, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,562 days).
Specimen C3N-02422-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afee74f4-c37d-4d1f-9417-2e5b9217202e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02422-71 (Blood Derived Normal), aliquot CPT0146910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bef4b8be-51de-4189-ac64-f2c91f6efdac

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 10, Intron 6, Nonsense Mutation 4, 5'UTR 3, Frame Shift Del 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKL3 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99527450; called by muse, mutect2, varscan2
- CENPF | c.5000G>A p.R1667Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201574754, COSV65276105; called by muse, mutect2, varscan2
- CHD5 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1399914278; called by muse, mutect2, varscan2
- CUX2 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV99919948; called by muse, mutect2
- EHBP1 | c.2588G>A p.R863Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as rs143133706; called by muse, mutect2, varscan2
- EPHA3 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 24/142 reads (17%) | catalogued as COSV60694913; called by muse, mutect2, varscan2
- EXO1 | c.2081A>G p.Q694R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs763404987; called by muse, mutect2, varscan2
- GRM8 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs140162343; called by muse, mutect2, varscan2
- ITSN2 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as rs1254470703, COSV61946700; called by muse, mutect2
- METTL21C | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs753242037, COSV57433768; called by muse, mutect2, varscan2
- MLH3 | c.2075C>T p.T692I | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs758928746; called by muse, mutect2, varscan2
- MYO18B | c.4912C>T p.R1638W | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs200771643; called by muse, mutect2, varscan2
- NAV3 | c.6460G>A p.G2154R (on ENST00000397909 / NM_001024383.2; = p.G2132R on NM_014903.6) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57110335; called by muse, mutect2, varscan2
- NDUFB4 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1283578690, COSV51742567; called by muse, mutect2, varscan2
- NEUROD6 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 115/395 reads (29%) | catalogued as rs1183382119, COSV51770486; called by muse, mutect2, varscan2
- NFE2L3 | c.1448_1449del p.S483* | Frame Shift Del (DEL) | VAF 63/312 reads (20%) | catalogued as rs762784890; called by mutect2, pindel, varscan2
- PPP1R1C | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs749911538; called by muse, mutect2, varscan2
- RNF152 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777583010, COSV57187398; called by muse, mutect2, varscan2
- ROS1 | c.5445C>G p.C1815W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63853147; called by muse, mutect2, varscan2
- TULP4 | c.3838C>A p.P1280T | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65581794; called by muse, mutect2, varscan2
- VAV3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764254114, COSV58392408; called by mutect2, varscan2
- ATP11A | c.2893T>G p.F965V | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CEP95 | c.1785del p.E595Dfs*21 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
- EML1 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO32 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GAS2L2 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 23/174 reads (13%) | called by muse, mutect2, varscan2
- IL17RE | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LILRB1 | c.703G>A p.A235T (on ENST00000427581; = p.A199T on NM_006669.6) | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MBP | c.400_413del p.M134Efs*35 (on ENST00000355994 / NM_001025101.2; = p.M1_?5 on NM_002385.3) | Frame Shift Del (DEL) | VAF 38/260 reads (15%) | called by mutect2, pindel
- MGA | c.6128C>T p.A2043V (on ENST00000219905 / NM_001164273.1; = p.A1834V on NM_001080541.2) | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBPF3 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NHLRC2 | c.533T>C p.L178S | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- OR11H7 | c.751T>C p.F251L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR11H7 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- OR1L6 | c.857C>A p.A286D (on ENST00000373684; = p.A250D on NM_001004453.2) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PCDHB7 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.403); called by muse, mutect2
- PER3 | c.2770C>A p.P924T | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PKD1 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- PLCB4 | c.3480G>C p.M1160I (on ENST00000278655 / NM_182797.3; = p.G1173R on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- PLEKHG7 | c.1617A>C p.E539D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- R3HCC1L | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- RASL11A | c.278C>G p.P93R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINH1 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 67/369 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SERPINH1 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIK3 | c.46C>A p.P16T (on ENST00000445177 / NM_001366686.2; = p.P22T on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- SLC16A12 | c.420T>A p.H140Q | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SLC24A1 | c.2456G>C p.G819A | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STOX2 | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2
- TGM4 | c.1829A>G p.K610R | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TTC14 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- USP25 | c.1834A>G p.I612V | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF554 | c.1282A>T p.R428W | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATAD1 | c.708T>C p.A236= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as rs777457295; called by muse, mutect2, varscan2
- GATA1 | c.282C>T p.A94= | Silent (SNP) | VAF 28/196 reads (14%) | catalogued as rs782123071, COSV64962245; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGF2BP2 | c.426G>A p.G142= | Silent (SNP) | VAF 40/368 reads (11%) | catalogued as rs748998986, COSV60490670; called by muse, mutect2, varscan2
- MAP3K3 | c.1278G>A p.Q426= | Silent (SNP) | VAF 46/328 reads (14%) | catalogued as rs372472600; called by muse, mutect2, varscan2
- OR11H7 | c.753C>T p.F251= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs1178525170; called by muse, varscan2
- RBPJL | c.357G>A p.T119= | Silent (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- SLC13A5 | c.663C>A p.T221= | Silent (SNP) | VAF 29/226 reads (13%) | called by muse, mutect2, varscan2
- TEX13C | c.639G>A p.Q213= | Silent (SNP) | VAF 58/349 reads (17%) | called by muse, mutect2, varscan2
- TRPM1 | c.615C>T p.S205= | Silent (SNP) | VAF 34/436 reads (8%) | catalogued as rs771401431, COSV99856245; called by muse, mutect2
- USP10 | c.213G>A p.L71= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV54753241; called by muse, mutect2, varscan2
- CHD4 | c.4022-19C>T | Intron (SNP) | VAF 3/41 reads (7%) | catalogued as COSV58906976; called by muse, mutect2
- CLDN5 | c.-55G>A | 5'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2
- DHCR24 | c.231+169G>A | Intron (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- DHRS7B | c.-39C>T | 5'UTR (SNP) | VAF 24/159 reads (15%) | catalogued as rs764853081; called by muse, mutect2, varscan2
- EIF4A2 | c.771+119_771+121del | Intron (DEL) | VAF 13/91 reads (14%) | catalogued as rs1232279858; called by pindel, varscan2
- KIF13A | c.-63C>T | 5'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- PTK2 | c.1417+318A>T | Intron (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- SHLD2 | c.1964-4127G>T | Intron (SNP) | VAF 29/250 reads (12%) | called by muse, mutect2, varscan2
- STX1B | c.*2C>G | 3'UTR (SNP) | VAF 13/122 reads (11%) | catalogued as COSV52681124; called by muse, mutect2, varscan2
- URM1 | c.237+98del | Intron (DEL) | VAF 22/218 reads (10%) | called by mutect2, pindel
